Somatic mutation profile of tumor specimen TCGA-VS-A9V4-01A (aliquot TCGA-VS-A9V4-01A-12D-A42O-09) from TCGA case TCGA-VS-A9V4, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Mucinous adenocarcinoma, endocervical type; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 63.9 years (23,334 days).
Specimen TCGA-VS-A9V4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e2cebdd2-dde5-4efb-9a66-856ebac5ed99.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VS-A9V4-10A (Blood Derived Normal), aliquot TCGA-VS-A9V4-10A-01D-A42R-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2f9f6348-255c-4b3a-ac91-f63c0afbb67f

The open-access MAF lists 125 somatic variants for this specimen: 93 protein-altering or splice-affecting, 29 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 83, Silent 29, Nonsense Mutation 5, Splice Site 2, Intron 2, Splice Region 1, RNA 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ATRX | c.4276C>T p.R1426* | Nonsense Mutation (SNP) | VAF 8/94 reads (9%) | hotspot (GDC flag); catalogued as rs919106518, COSV64870782; called by muse, mutect2
- ACAP2 | c.2309G>A p.R770H | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); catalogued as rs147239672; called by muse, mutect2, varscan2
- ACSM2B | c.196A>C p.S66R | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT tolerated (0.06); PolyPhen benign (0.006); catalogued as COSV100312742; called by muse, mutect2, varscan2
- ADAM15 | c.307G>T p.D103Y | Missense Mutation (SNP) | VAF 8/68 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99665039; called by muse, varscan2
- ANKRD6 | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT tolerated (0.09); PolyPhen benign (0.118); catalogued as rs200509240, COSV60232614; called by muse, mutect2, varscan2
- APC | c.646-1G>A p.X216_splice | Splice Site (SNP) | VAF 29/104 reads (28%) | catalogued as CS971608, COSV57347627, COSV99970657; called by muse, mutect2, varscan2
- ASCC3 | c.685A>T p.K229* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV100225839; called by muse, mutect2, varscan2
- BMP6 | c.991G>A p.V331M | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs781335360, COSV99307055; called by muse, mutect2, varscan2
- C12orf4 | c.1566G>A p.Q522= | Splice Region (SNP) | VAF 12/66 reads (18%) | catalogued as COSV99712767, COSV99712987; called by muse, mutect2, varscan2
- C22orf15 | c.391C>T p.R131W | Missense Mutation (SNP) | VAF 3/27 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.043); catalogued as rs374945245, COSV100533656; called by muse, mutect2
- CEP85L | c.341T>G p.L114R | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as COSV63821769; called by muse, mutect2, varscan2
- CHERP | c.2402G>A p.R801Q | Missense Mutation (SNP) | VAF 20/129 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.885); catalogued as COSV52225442; called by muse, mutect2, varscan2
- CLCN4 | c.77C>T p.T26M | Missense Mutation (SNP) | VAF 11/55 reads (20%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.856); catalogued as COSV66466160; called by muse, mutect2, varscan2
- CSMD1 | c.3064C>T p.R1022W (on ENST00000520002; = p.R1021W on NM_033225.6) | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs753228331, COSV59280570; called by muse, mutect2, varscan2
- CTNNA2 | c.2340A>C p.Q780H | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100560958, COSV100562214; called by muse, mutect2, varscan2
- CUZD1 | c.1576T>C p.S526P | Missense Mutation (SNP) | VAF 12/85 reads (14%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.963); catalogued as COSV100158845; called by muse, mutect2, varscan2
- DCAF17 | c.1174A>T p.N392Y | Missense Mutation (SNP) | VAF 35/106 reads (33%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100266176; called by muse, mutect2, varscan2
- DCLK1 | c.1103A>C p.N368T | Missense Mutation (SNP) | VAF 13/81 reads (16%) | SIFT tolerated (0.58); PolyPhen benign (0.006); catalogued as COSV99711570; called by muse, mutect2, varscan2
- DCLK1 | c.121T>G p.F41V | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV99711573; called by muse, mutect2, varscan2
- DIAPH3 | c.2642C>T p.T881M (on ENST00000400324 / NM_001042517.2; = p.T618M on NM_030932.3) | Missense Mutation (SNP) | VAF 21/155 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs932213809, COSV99933694; called by muse, mutect2, varscan2
- DLG1 | c.784G>T p.G262* | Nonsense Mutation (SNP) | VAF 12/92 reads (13%) | catalogued as COSV100015444; called by muse, mutect2, varscan2
- DMXL1 | c.1340T>G p.L447R | Missense Mutation (SNP) | VAF 19/60 reads (32%) | SIFT tolerated (0.52); PolyPhen benign (0.021); catalogued as COSV100224157; called by muse, mutect2, varscan2
- EFHC2 | c.754C>A p.H252N | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.658); catalogued as COSV101375487, COSV69553733; called by muse, mutect2, varscan2
- EIF3I | c.28G>A p.E10K | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.145); catalogued as COSV100557206; called by muse, mutect2, varscan2
- EPHB6 | c.1161G>T p.M387I | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.087); catalogued as rs752265529, COSV101235981; called by muse, mutect2, varscan2
- FAM9A | c.112T>G p.F38V | Missense Mutation (SNP) | VAF 6/76 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.427); catalogued as COSV101121349; called by muse, mutect2
- FBN3 | c.2554G>A p.D852N | Missense Mutation (SNP) | VAF 14/74 reads (19%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.999); catalogued as rs775885971, COSV99560473; called by muse, mutect2, varscan2
- FCHO2 | c.1223C>T p.T408I | Missense Mutation (SNP) | VAF 73/211 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.143); catalogued as rs1191520529, COSV100530751; called by muse, mutect2, varscan2
- FLNC | c.4480C>T p.R1494W | Missense Mutation (SNP) | VAF 18/135 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.511); catalogued as rs779079128, COSV100367757; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GABBR1 | c.1253C>T p.A418V | Missense Mutation (SNP) | VAF 6/59 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as COSV100589754; called by muse, mutect2, varscan2
- GALT | c.877T>G p.S293A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.945); catalogued as COSV100535373; called by muse, mutect2, varscan2
- GLUL | c.1039G>A p.D347N | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs1210135609, COSV100092028; called by muse, mutect2, varscan2
- GRIA1 | c.2680A>G p.S894G | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated, low confidence (0.41); PolyPhen benign (0); catalogued as COSV53607778, COSV99598242; called by muse, mutect2, varscan2
- GUCY1A1 | c.627A>T p.R209S | Missense Mutation (SNP) | VAF 10/55 reads (18%) | SIFT tolerated (0.51); PolyPhen benign (0.01); catalogued as rs963953542, COSV99637862; called by muse, mutect2, varscan2
- HELB | c.470T>C p.L157P | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.081); catalogued as COSV99921950; called by muse, mutect2, varscan2
- HPCA | c.67T>C p.S23P | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT deleterious (0.03); PolyPhen benign (0.103); catalogued as COSV100992184; called by muse, mutect2, varscan2
- HTR7 | c.1286A>C p.E429A | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as COSV53284478, COSV53289936; called by muse, mutect2, varscan2
- IPO7 | c.1976C>T p.A659V | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.042); catalogued as COSV63352605; called by muse, mutect2
- KCNT2 | c.806T>G p.V269G | Missense Mutation (SNP) | VAF 11/82 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99654232, COSV99655098; called by muse, mutect2, varscan2
- KIAA1549 | c.1471G>A p.V491I | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as rs749611621, COSV54325434; called by muse, mutect2, varscan2
- KLHL11 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT tolerated (0.22); PolyPhen benign (0.239); catalogued as COSV100044352; called by muse, mutect2
- LAMA4 | c.4492C>T p.R1498C (on ENST00000230538 / NM_001105206.3; = p.R1491C on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.765); catalogued as rs782368185, COSV57898099; called by muse, mutect2, varscan2
- LMAN1L | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100547725; called by muse, mutect2, varscan2
- LRP1B | c.4006A>G p.T1336A | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.277); catalogued as COSV67253201; called by muse, mutect2, varscan2
- LRP2 | c.5018G>A p.G1673E | Missense Mutation (SNP) | VAF 36/109 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99788756; called by muse, mutect2, varscan2
- LRRC8A | c.2383C>G p.P795A | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.248); catalogued as COSV52184274, COSV99396652; called by muse, mutect2
- MBD5 | c.196T>C p.C66R | Missense Mutation (SNP) | VAF 15/123 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101290110; called by muse, mutect2, varscan2
- MEF2C | c.752G>A p.R251H | Missense Mutation (SNP) | VAF 29/130 reads (22%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.992); catalogued as COSV60925868; called by muse, mutect2, varscan2
- MYO7B | c.3857G>A p.R1286Q | Missense Mutation (SNP) | VAF 12/50 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs375117051; called by muse, mutect2, varscan2
- NUP98 | c.4852G>A p.E1618K (on ENST00000359171 / NM_001365126.1; = p.E1601K on NM_016320.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/100 reads (17%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.728); catalogued as rs372799391; called by muse, mutect2, varscan2
- OR13G1 | c.245T>C p.M82T | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.006); catalogued as rs757531066, COSV100687299; called by mutect2, varscan2
- OR2M2 | c.774G>A p.M258I | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100677239; called by muse, mutect2, varscan2
- OR5H15 | c.49T>C p.F17L | Missense Mutation (SNP) | VAF 34/212 reads (16%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs752173661, COSV100736680; called by muse, mutect2, varscan2
- OR5M1 | c.270G>C p.K90N | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.963); catalogued as rs532045516, COSV101591561, COSV73202033, COSV73202262; called by muse, mutect2, varscan2
- PCDH15 | c.4262C>T p.A1421V | Missense Mutation (SNP) | VAF 16/86 reads (19%) | SIFT tolerated (0.16); PolyPhen benign (0.21); catalogued as rs1329914600, COSV57262088; called by muse, mutect2, varscan2
- PCDHGB4 | c.1540G>A p.A514T | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as rs746873845, COSV99539501; called by muse, mutect2, varscan2
- PDGFC | c.126A>C p.Q42H | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV99925464; called by muse, mutect2, varscan2
- PDS5B | c.1654G>A p.V552M | Missense Mutation (SNP) | VAF 24/179 reads (13%) | SIFT tolerated (0.25); PolyPhen probably damaging (0.991); catalogued as rs766659799, COSV100221033; called by muse, mutect2, varscan2
- PEG3 | c.1792C>T p.R598C | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.725); catalogued as rs138383423; called by muse, mutect2, varscan2
- PEX14 | c.761C>T p.A254V | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs149265608; called by muse, mutect2, varscan2
- PIK3CA | c.2975G>C p.R992P | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55873844, COSV55878461, COSV55906410; called by muse, mutect2
- PJA1 | c.817A>C p.I273L | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT tolerated (0.3); PolyPhen benign (0.003); catalogued as COSV100824736, COSV64052499; called by muse, mutect2, varscan2
- PLAA | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.418); catalogued as rs1006514199, COSV101263521; called by muse, mutect2, varscan2
- PLEKHH2 | c.1037C>T p.P346L | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as rs1407513692, COSV99174808; called by muse, mutect2, varscan2
- POMP | c.34G>T p.D12Y | Missense Mutation (SNP) | VAF 21/91 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.879); catalogued as COSV101076873; called by muse, mutect2, varscan2
- PRAMEF6 | c.332A>C p.N111T | Missense Mutation (SNP) | VAF 26/173 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV100755862; called by muse, varscan2
- PTAFR | c.391C>T p.R131C | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs542211181, COSV59537072; called by muse, mutect2, varscan2
- PTPRT | c.1262A>T p.N421I | Missense Mutation (SNP) | VAF 9/57 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs773703805, COSV100627867, COSV62030250; called by muse, mutect2, varscan2
- RWDD3 | c.251A>G p.K84R | Missense Mutation (SNP) | VAF 31/89 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as COSV99811612; called by muse, mutect2, varscan2
- SALL1 | c.151G>A p.E51K | Missense Mutation (SNP) | VAF 18/115 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs1047565580, COSV51764485, COSV51765123; called by muse, mutect2, varscan2
- SASS6 | c.158A>T p.D53V | Missense Mutation (SNP) | VAF 43/183 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1207224228, COSV99790883; called by muse, mutect2, varscan2
- SDK1 | c.4888G>T p.E1630* | Nonsense Mutation (SNP) | VAF 14/43 reads (33%) | catalogued as COSV101269439, COSV67364719; called by muse, mutect2, varscan2
- SEMG2 | c.1404C>A p.Y468* | Nonsense Mutation (SNP) | VAF 16/119 reads (13%) | catalogued as rs372989211; called by muse, mutect2, varscan2
- SPATS2 | c.767G>A p.R256Q | Missense Mutation (SNP) | VAF 26/236 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.046); catalogued as rs769173005, COSV58924095; called by muse, mutect2, varscan2
- SPTA1 | c.604G>C p.D202H | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV100935078, COSV100935881; called by muse, mutect2, varscan2
- SRGAP2 | c.2317G>A p.D773N (on ENST00000624873 / NM_001170637.4; = p.D774N on NM_015326.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.199); catalogued as rs781908994, COSV99832897; called by muse, mutect2, varscan2
- SS18L1 | c.758A>G p.Y253C | Missense Mutation (SNP) | VAF 17/142 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as rs1485571211, COSV100064964; called by muse, mutect2, varscan2
- SSTR4 | c.458G>A p.R153H | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.427); catalogued as rs542657849, COSV54796687, COSV99658529; called by muse, mutect2, varscan2
- STK10 | c.1186G>A p.V396M | Missense Mutation (SNP) | VAF 45/82 reads (55%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs902986585, COSV99451664; called by muse, varscan2
- SULF2 | c.850T>A p.L284M | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.329); catalogued as COSV100737229; called by muse, mutect2, varscan2
- SYNE1 | c.11414G>A p.R3805Q (on ENST00000367255 / NM_182961.4; = p.R3790Q on NM_033071.3) | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs754270893, COSV54921171, COSV55010734; called by muse, mutect2, varscan2
- TBK1 | c.1760+4_1760+7del p.X587_splice | Splice Site (DEL) | VAF 6/37 reads (16%) | catalogued as rs753802322; called by pindel, varscan2
- THSD7B | c.2636A>C p.K879T | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.905); catalogued as COSV99752170; called by muse, mutect2, varscan2
- TMED1 | c.110T>C p.L37P | Missense Mutation (SNP) | VAF 11/59 reads (19%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.953); catalogued as COSV99284169; called by muse, mutect2, varscan2
- TMEM74 | c.498A>C p.E166D | Missense Mutation (SNP) | VAF 22/94 reads (23%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); catalogued as COSV99865707; called by muse, mutect2, varscan2
- TP53 | c.80del p.P27Lfs*17 | Frame Shift Del (DEL) | VAF 12/35 reads (34%) | catalogued as rs1192416464, COSV53662521; called by mutect2, pindel, varscan2
- VXN | c.184G>A p.G62R | Missense Mutation (SNP) | VAF 14/66 reads (21%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1157329377, COSV59685822; called by muse, mutect2, varscan2
- XPC | c.2590C>T p.R864C | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs373301509, COSV53204808; called by muse, mutect2, varscan2
- YDJC | c.892G>A p.D298N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.967); catalogued as COSV53037575; called by muse, mutect2, varscan2
- ZNF385A | c.299G>C p.R100P (on ENST00000338010 / NM_001130967.3; = p.R80P on NM_015481.3) | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100566887; called by muse, mutect2, varscan2
- ZNF587 | c.1217G>A p.R406K | Missense Mutation (SNP) | VAF 17/87 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.022); catalogued as COSV100299515, COSV57150272; called by muse, mutect2, varscan2
- ZNF768 | c.1157C>T p.S386L | Missense Mutation (SNP) | VAF 8/65 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.77); catalogued as rs769503822, COSV63320302; called by muse, mutect2, varscan2
- CDC16 | c.1363dup p.C455Lfs*5 | Frame Shift Ins (INS) | VAF 35/192 reads (18%) | called by mutect2, pindel, varscan2
- ALOX5AP | c.135C>T p.T45= | Silent (SNP) | VAF 28/94 reads (30%) | catalogued as rs372030223; called by muse, mutect2, varscan2
- CAPN6 | c.954T>C p.S318= | Silent (SNP) | VAF 15/100 reads (15%) | catalogued as COSV100136901; called by muse, mutect2, varscan2
- CDH23 | c.612G>T p.T204= | Silent (SNP) | VAF 10/36 reads (28%) | catalogued as COSV99821353; called by muse, mutect2, varscan2
- ELF4 | c.165C>T p.D55= | Silent (SNP) | VAF 27/69 reads (39%) | catalogued as rs138080359, COSV57454541; called by muse, mutect2, varscan2
- FGD5 | c.1353C>T p.D451= | Silent (SNP) | VAF 19/73 reads (26%) | catalogued as rs374381042; called by muse, mutect2, varscan2
- GABRR2 | c.624G>T p.L208= | Silent (SNP) | VAF 20/91 reads (22%) | catalogued as COSV101298977, COSV68765066; called by muse, mutect2, varscan2
- IGSF5 | c.765G>A p.P255= | Silent (SNP) | VAF 22/77 reads (29%) | catalogued as rs767089384, COSV66031396; called by muse, mutect2, varscan2
- KRT14 | c.72C>T p.I24= | Silent (SNP) | VAF 88/526 reads (17%) | catalogued as rs1385729323, COSV99391000; called by muse, mutect2, varscan2
- KRT85 | c.219C>T p.A73= | Silent (SNP) | VAF 12/70 reads (17%) | catalogued as COSV99225488; called by muse, mutect2, varscan2
- MAP2 | c.4491T>G p.T1497= | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV99560318; called by muse, mutect2, varscan2
- MED17 | c.27C>T p.I9= | Silent (SNP) | VAF 25/93 reads (27%) | catalogued as rs376774687; called by muse, mutect2, varscan2
- MED24 | c.1608G>A p.E536= | Silent (SNP) | VAF 6/80 reads (8%) | catalogued as COSV100673216; called by muse, mutect2
- MUC5B | c.3867C>T p.C1289= | Silent (SNP) | VAF 23/43 reads (53%) | catalogued as rs774852919, COSV71590967; called by muse, mutect2, varscan2
- OBSCN | c.18540C>T p.Y6180= | Silent (SNP) | VAF 22/89 reads (25%) | catalogued as rs867768180, COSV52796666; called by muse, mutect2, varscan2
- OR1C1 | c.684C>A p.I228= | Silent (SNP) | VAF 6/19 reads (32%) | catalogued as COSV101376233, COSV68716308; called by muse, mutect2, varscan2
- OTUD5 | c.978T>C p.R326= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV99332011; called by muse, mutect2
- PCDH17 | c.3214T>C p.L1072= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs1320589035, COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PCDHGB5 | c.1320C>T p.D440= | Silent (SNP) | VAF 5/41 reads (12%) | called by muse, mutect2, varscan2
- PDPR | c.1249C>T p.L417= | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV99848149; called by muse, mutect2, varscan2
- PHC2 | c.1521C>A p.P507= | Silent (SNP) | VAF 9/63 reads (14%) | catalogued as COSV99931134; called by muse, mutect2, varscan2
- PNMA5 | c.1119T>G p.S373= | Silent (SNP) | VAF 7/29 reads (24%) | catalogued as COSV100721649; called by muse, mutect2, varscan2
- POM121L12 | c.849C>T p.F283= | Silent (SNP) | VAF 16/51 reads (31%) | catalogued as rs756006889, COSV68692136, COSV68693268; called by muse, mutect2, varscan2
- RASGRF1 | c.225C>T p.R75= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as rs146718030, COSV101369655; called by muse, mutect2, varscan2
- RNF182 | c.213G>A p.T71= | Silent (SNP) | VAF 15/51 reads (29%) | catalogued as rs748959887, COSV101337913; called by muse, mutect2, varscan2
- SLC1A5 | c.1425C>T p.D475= | Silent (SNP) | VAF 8/40 reads (20%) | catalogued as rs762659867, COSV101314786; called by muse, mutect2, varscan2
- SLC38A5 | c.1218C>T p.S406= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs1556961395, COSV100476545; called by muse, mutect2, varscan2
- TTN | c.67116G>A p.E22372= (on ENST00000591111; = p.E14948= on NM_003319.4) | Silent (SNP) | VAF 6/64 reads (9%) | catalogued as COSV100616104; called by muse, mutect2
- ZNF582 | c.15A>G p.S5= | Silent (SNP) | VAF 8/57 reads (14%) | catalogued as COSV100018739; called by muse, mutect2, varscan2
- ZRANB3 | c.1377G>A p.L459= | Silent (SNP) | VAF 13/95 reads (14%) | catalogued as COSV99923817; called by muse, mutect2, varscan2
- AC024940.1 | n.2836A>G | RNA (SNP) | VAF 39/247 reads (16%) | called by muse, mutect2, varscan2
- ADSS1 | c.193-4889G>T | Intron (SNP) | VAF 11/69 reads (16%) | catalogued as COSV100272296; called by muse, mutect2, varscan2
- LIN7A | c.82+1854G>A | Intron (SNP) | VAF 5/51 reads (10%) | catalogued as rs374241904; called by muse, mutect2, varscan2
